Somatic mutation profile of tumor specimen TARGET-30-PAURPL-01A (aliquot TARGET-30-PAURPL-01A-01D) from TARGET case TARGET-30-PAURPL, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 9.5 years (3,456 days).
Specimen TARGET-30-PAURPL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbf85242-70c9-4762-ab6e-214bea5a734c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAURPL-10A (Blood Derived Normal), aliquot TARGET-30-PAURPL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88122a78-a1bc-479e-b906-19d33ae17bb2

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEFH | c.2487G>T p.K829N | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV60220961; called by muse, mutect2, varscan2
- ROR1 | c.2171T>A p.L724H | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64293620; called by muse, mutect2, varscan2
- STAG2 | c.3538G>T p.G1180W | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as COSV54373267; called by muse, mutect2, varscan2
- ATRX | c.6339_6342del p.F2113Lfs*9 | Frame Shift Del (DEL) | VAF 39/95 reads (41%) | called by mutect2, pindel, varscan2
